Gene-level copy-number profile of tumor specimen TCGA-UC-A7PF-01A from TCGA case TCGA-UC-A7PF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 44.9 years (16,412 days).
Specimen TCGA-UC-A7PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.7cca71cd-228c-4af7-9dd9-4edf5635e8fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UC-A7PF-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6112001d-5972-4eab-a6c1-bdc3405dfe22

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,976; copy number 3: 92; copy number 4: 39,256; copy number 5: 3,533; copy number 6: 9,738; copy number 8: 2,008; copy number 9: 4; copy number 10: 13; copy number 11: 12; copy number 14: 48; copy number 23: 10; copy number 31: 7; copy number 41: 77; copy number 45: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UC-A7PF-01A-11D-A350-01): tumor purity 0.55, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 212 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,257,772–37,699,306, 13 genes, copy number 10: TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr7:124,742,312–125,482,966, 12 genes, copy number 11: AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr8:127,289,817–127,482,139, 1 gene, copy number 9 (within-gene range 4–9): CASC8.
- chr8:127,322,183–127,420,066, 2 genes, copy number 9 (within-gene range 4–9): POU5F1B, CCAT2.
- chr9:14,475–14,398,983, 184 genes, copy number 14–45 (within-gene range 4–45) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
